Gene-level copy-number profile of tumor specimen ALCH-B1UE-TTP1-A from ALCHEMIST case ALCH-B1UE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.7 years (18,524 days).
Specimen ALCH-B1UE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3e812998-011b-4695-b47e-a639487f6113.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1UE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/bce43c71-593b-4331-8c12-6d305da7e00d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,950; copy number 2: 50,518; copy number 3: 3,571; copy number 4: 84; copy number 5: 135; copy number 6: 33; copy number 7: 48; copy number 9: 5; copy number 10: 37; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–1): AL512383.1.
- chr3:50,419,781–50,419,899, 1 gene (within-gene range 0–1): RNA5SP131.
- chr9:127,940,582–127,980,989, 1 gene (within-gene range 0–2): FAM102A.
- chr10:124,996,064–125,001,491, 1 gene (within-gene range 0–1): AL731571.1.
- chr16:54,239,693–54,240,654, 1 gene: AC007907.1.
- chr19:54,209,092–54,209,418, 1 gene (within-gene range 0–1): AC245052.2.
- chr22:21,290,760–21,325,042, 3 genes (within-gene range 0–2): BCRP6, FAM230H, AP000552.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 259 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,843,268–38,163,772, 16 genes, copy number 5 (within-gene range 3–5): BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3.
- chr8:38,223,957–39,417,378, 30 genes, copy number 6: AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5.
- chr8:39,522,976–39,730,065, 2 genes, copy number 6: AC123767.1, ADAM18.
- chr9:34,179,005–35,003,663, 45 genes, copy number 7–10: UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1, RPP25L, DCTN3, ARID3C, SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2, CCL19, AL162231.5, CCL21, FAM205A, AL589645.1, FAM205BP, FAM205C, GLULP4, YWHAZP6, PHF24, DNAJB5-DT, DNAJB5, AL355377.1, AL355377.2.
- chr9:35,406,755–36,014,623, 45 genes, copy number 7 (within-gene range 1–7): ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P.
- chr11:72,685,069–72,793,599, 1 gene, copy number 5 (within-gene range 2–5): ARAP1.
- chr11:72,689,650–73,970,366, 38 genes, copy number 5 (within-gene range 2–5): AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13.
- chr11:74,988,279–75,351,705, 16 genes, copy number 5: NEU3, AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326.
- chr15:21,298,233–21,981,245, 39 genes, copy number 5–18: AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr18:630,886–1,408,344, 26 genes, copy number 5 (within-gene range 2–5): TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr22:21,341,595–21,345,258, 1 gene, copy number 6: PPP1R26P5.

Autosomal genes at a single copy (total copy number 1): 3,950. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
